Gene-level copy-number profile of tumor specimen TCGA-OR-A5JP-01A from TCGA case TCGA-OR-A5JP, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 40.2 years (14,667 days).
Specimen TCGA-OR-A5JP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.e79049b4-162c-40c3-b550-d4961c03fa52.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/47518bfd-9236-408c-a4f9-354577e57597

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,841; copy number 2: 11,186; copy number 3: 20,318; copy number 4: 12,759; copy number 5: 10,577; copy number 6: 1,805; copy number 7: 189; copy number 9: 139.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JP-01A-11D-A29H-01): tumor purity 0.8, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 328 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:38,360,427–43,045,120, 139 genes, copy number 9 (broad region; genes not listed).
- chr19:20,553,792–28,970,874, 189 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 466. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
